Somatic mutation profile of tumor specimen TARGET-10-PAPGMT-09A (aliquot TARGET-10-PAPGMT-09A-01D) from TARGET case TARGET-10-PAPGMT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,372 days).
Specimen TARGET-10-PAPGMT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d5e4aee-d9af-4a3d-9a01-fd010a33ed9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPGMT-10A (Blood Derived Normal), aliquot TARGET-10-PAPGMT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ed78aa8-c11c-4dfb-a5db-cdcf5acc494c

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Intron 1, 3'UTR 1, Splice Region 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 37/94 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.211T>C p.F71L | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs397507512, CM030494, CM056378, COSV61006422; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATN1 | c.3216C>T p.A1072= | Splice Region (SNP) | VAF 18/47 reads (38%) | catalogued as COSV57547181; called by mutect2, varscan2
- FRMPD3 | c.4582C>T p.R1528C | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1337963429, COSV52193814; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XIRP2 | c.8753G>A p.R2918H (on ENST00000628543; = p.R3093H on NM_152381.6) | Missense Mutation (SNP) | VAF 129/347 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs576110894, COSV54679955; called by muse, mutect2, varscan2
- KIF1A | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRATD1 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SAMD14 | c.621_630dup p.K211Pfs*46 | Frame Shift Ins (INS) | VAF 10/56 reads (18%) | called by mutect2, varscan2
- UBE4A | c.2036A>C p.K679T (on ENST00000252108 / NM_001204077.2; = p.K686T on NM_004788.4) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- ATAD5 | c.2163T>G p.T721= | Silent (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- KCNA1 | c.369C>T p.G123= | Silent (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- ADGRA1 | c.3+135C>T | Intron (SNP) | VAF 20/67 reads (30%) | catalogued as rs941222912; called by muse, mutect2, varscan2
- VWFP1 | n.1089C>T | RNA (SNP) | VAF 14/57 reads (25%) | catalogued as rs1208063830; called by muse, mutect2
- ZFPL1 | c.*116T>C | 3'UTR (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
